CCDI case PBCPRS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e5ad4b72-771a-4510-8025-d0220a7194c2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation: ICD-O-3 morphology code: 9561/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 21.6 years (7,900 days).

Biospecimens (3 samples)
- Sample 0DXCTZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXCUB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DXCUH: Tissue type: Tumor; Specimen type: Solid Tissue.
